Somatic mutation profile of tumor specimen TCGA-VQ-A8DZ-01A (aliquot TCGA-VQ-A8DZ-01A-11D-A364-08) from TCGA case TCGA-VQ-A8DZ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 70.8 years (25,863 days).
Specimen TCGA-VQ-A8DZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e4004a2-48fd-4128-8296-fbcefea47e4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8DZ-10A (Blood Derived Normal), aliquot TCGA-VQ-A8DZ-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd48b77f-5d4d-423b-8fd1-16ebe339cefa

The open-access MAF lists 86 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 18, Nonsense Mutation 2, Translation Start Site 1, In Frame Ins 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 44/105 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as rs587782197, COSV52676080, COSV52724970, COSV52728973; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11117T>G p.V3706G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV101446692; called by muse, mutect2
- ACTL7A | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs777158390, COSV100452976; called by muse, mutect2, varscan2
- AKAP6 | c.4759A>G p.S1587G | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99797241; called by muse, mutect2, varscan2
- AL645922.1 | c.1888T>G p.S630A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV100190449; called by muse, mutect2, varscan2
- ATP5PD | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.966); catalogued as COSV100043095; called by muse, mutect2
- C7 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495209; called by muse, mutect2
- CACNA2D3 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752111419, COSV99868113; called by muse, mutect2, varscan2
- CASP8AP2 | c.3853C>A p.P1285T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV99386671; called by muse, mutect2
- CCDC92 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV99435052; called by muse, mutect2, varscan2
- CDH19 | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV50956632; called by muse, mutect2, varscan2
- CTNNBIP1 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV101032653; called by muse, mutect2, varscan2
- DDX60 | c.4415C>T p.S1472L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1221587237, COSV101190172, COSV101190524; called by muse, mutect2, varscan2
- DLG2 | c.262A>C p.N88H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99711787, COSV99720506; called by muse, mutect2, varscan2
- E2F7 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100523173; called by muse, mutect2, varscan2
- ELF1 | c.1355T>A p.I452K | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV53498427, COSV99522753; called by muse, mutect2, varscan2
- EPHA5 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs1410955850, COSV56637070; called by muse, mutect2, varscan2
- ERICH3 | c.3292C>G p.L1098V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV100443065, COSV100444100; called by muse, mutect2, varscan2
- FCHO1 | c.1004-1C>T p.X335_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as rs772008992, COSV53183307; called by muse, mutect2
- FGA | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV57396973; called by muse, mutect2, varscan2
- GAL3ST3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV61749517; called by muse, mutect2
- GAPVD1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.972); catalogued as rs373955222; called by muse, mutect2, varscan2
- GK2 | c.445T>G p.F149V | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725838; called by muse, mutect2
- GYS2 | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.641); catalogued as COSV99679287; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs775417213; called by muse, mutect2, varscan2
- IGSF9B | c.2735T>G p.L912R | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100316727; called by muse, mutect2, varscan2
- ITPR1 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773337674, COSV56984100; called by muse, mutect2
- KCNA5 | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV99363493; called by muse, mutect2, varscan2
- LTBP2 | c.4032G>A p.V1344= | Splice Region (SNP) | VAF 3/25 reads (12%) | catalogued as rs1227025858, COSV99999372; called by muse, mutect2
- MTHFD1L | c.990G>A p.M330I | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100943362; called by muse, mutect2, varscan2
- MTUS1 | c.722T>C p.M241T | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100028598; called by muse, mutect2
- MYT1L | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs781013816, COSV67723791; called by mutect2, varscan2
- NEGR1 | c.369A>T p.Q123H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV100159877; called by muse, mutect2, varscan2
- NELL1 | c.666T>G p.N222K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100117630; called by muse, mutect2, varscan2
- NTNG1 | c.398A>C p.N133T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99634881; called by muse, mutect2, varscan2
- OR2T12 | c.29T>G p.F10C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100527462; called by muse, mutect2
- OR6M1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1275251039, COSV100483970; called by muse, mutect2, varscan2
- PCDH10 | c.1660C>A p.L554M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52105791; called by muse, mutect2, varscan2
- PIH1D2 | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99735193; called by muse, mutect2, varscan2
- PPFIA2 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100331194; called by muse, mutect2, varscan2
- PPFIA2 | c.928A>C p.K310Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100331198; called by muse, mutect2, varscan2
- RANGAP1 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs144343100, COSV100663604; called by muse, mutect2, varscan2
- RCC2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV100965097; called by mutect2, varscan2
- RDH10 | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99536000; called by muse, mutect2, varscan2
- RUVBL1 | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100493970; called by muse, mutect2, varscan2
- SERPINB4 | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV100345320; called by muse, mutect2, varscan2
- SETD4 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as rs1202557040, COSV59774293; called by muse, mutect2
- SIRPA | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100604941; called by muse, mutect2, varscan2
- SLC12A4 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs756214692, COSV100311047; called by muse, mutect2, varscan2
- SLC12A5 | c.3391G>A p.G1131S (on ENST00000454036 / NM_001134771.2; = p.G1108S on NM_020708.5) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1422241396, COSV51642106, COSV99275005; called by muse, mutect2, varscan2
- SLC24A2 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs757770140, COSV99645483; called by muse, mutect2, varscan2
- TAF1L | c.5178G>T p.E1726D | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs773418235, COSV99643830; called by muse, mutect2, varscan2
- TENM4 | c.4334C>A p.P1445H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53634535, COSV99569433; called by muse, mutect2, varscan2
- TMEM200C | c.1705G>T p.G569C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs527776822, COSV101274765; called by muse, varscan2
- TTN | c.15046T>C p.F5016L (on ENST00000591111; = p.F4089L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | PolyPhen benign (0.037); catalogued as COSV100588444; called by mutect2, varscan2
- TUBA3D | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.086); catalogued as COSV100342159; called by muse, mutect2
- VRTN | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1341359355, COSV56442642; called by muse, mutect2, varscan2
- XPNPEP2 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs762041216, COSV100941359; called by muse, mutect2, varscan2
- ZNF518B | c.143C>A p.S48* | Nonsense Mutation (SNP) | VAF 14/174 reads (8%) | catalogued as COSV100456513; called by muse, mutect2
- ZNF624 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100256909; called by muse, mutect2, varscan2
- ZNF782 | c.2069G>A p.R690K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as COSV100001043; called by muse, mutect2, varscan2
- ZNF99 | c.2309T>C p.F770S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101233617; called by muse, mutect2, varscan2
- MUC6 | c.6858_6859del p.S2287Tfs*86 | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | called by pindel, varscan2
- OLFM3 | c.1175G>T p.R392I (on ENST00000338858 / NM_001288821.1; = p.R372I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SACM1L | c.1444_1446dup p.Y482dup | In Frame Ins (INS) | VAF 6/60 reads (10%) | called by mutect2, pindel
- TASOR2 | c.5547_5548dup p.T1850Ifs*3 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- CAVIN1 | c.648C>T p.S216= | Silent (SNP) | VAF 59/156 reads (38%) | catalogued as COSV100824486; called by muse, mutect2, varscan2
- COL4A4 | c.3544T>C p.L1182= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs974232055, COSV100305872; called by muse, mutect2, varscan2
- HOXB4 | c.357G>A p.P119= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs1452546543, COSV100203646; called by muse, mutect2, varscan2
- HOXD3 | c.597G>C p.T199= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs774731900, COSV99979799; called by muse, mutect2
- LMO4 | c.309G>T p.A103= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs146253698, COSV65170113; called by muse, mutect2, varscan2
- NEK2 | c.300G>A p.K100= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100878489; called by muse, mutect2, varscan2
- NELL1 | c.667C>T p.L223= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV100117631; called by muse, mutect2, varscan2
- NGEF | c.558G>A p.S186= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs117250667, COSV99887603; called by muse, mutect2, varscan2
- NUP50 | c.1035C>T p.P345= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- PBLD | c.852C>G p.G284= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV99515953; called by muse, mutect2, varscan2
- PCDHB7 | c.1902C>T p.D634= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1554280305, COSV99175166, COSV99177276; called by muse, mutect2, varscan2
- PCLO | c.6375C>A p.L2125= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as rs1344874967, COSV100426062, COSV61625742; called by muse, mutect2, varscan2
- PKHD1L1 | c.8106G>A p.A2702= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as rs748123301, COSV65737973; called by muse, mutect2, varscan2
- PLXNA1 | c.1809C>T p.F603= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV52525050; called by muse, mutect2, varscan2
- PRR14 | c.162G>A p.V54= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99788219; called by muse, mutect2, varscan2
- SDF2 | c.261G>A p.K87= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99897792; called by muse, mutect2, varscan2
- TMCO6 | c.264C>T p.V88= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs112278925; called by mutect2, varscan2
- TMEM200C | c.1623G>T p.R541= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV101274766; called by muse, varscan2
- AMDHD2 | c.*982A>G | 3'UTR (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99565471; called by muse, varscan2
